Somatic mutation profile of tumor specimen TCGA-QL-A97D-01A (aliquot TCGA-QL-A97D-01A-12D-A40P-10) from TCGA case TCGA-QL-A97D, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 84.6 years (30,914 days).
Specimen TCGA-QL-A97D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612b7045-911e-4e06-b071-2e90fd09edd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QL-A97D-10A (Blood Derived Normal), aliquot TCGA-QL-A97D-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ae4018b-03b1-4f12-9a18-c4d00fb028d5

The open-access MAF lists 245 somatic variants for this specimen: 190 protein-altering or splice-affecting, 49 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 166, Silent 49, Nonsense Mutation 11, Frame Shift Del 10, Intron 2, RNA 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6 | c.2450A>G p.K817R | Missense Mutation (SNP) | VAF 38/140 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as COSV54704910, COSV54705322; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 52/191 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PLOD2 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 45/239 reads (19%) | catalogued as rs780770356, COSV51469342; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 32/60 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.348G>T p.Q116H | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100228630; called by muse, mutect2
- ADAMTS16 | c.2237C>T p.T746M | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs560563999, COSV56984274; called by muse, mutect2, varscan2
- ADAMTS2 | c.2556C>A p.D852E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.278); catalogued as COSV52382420, COSV99281300; called by muse, mutect2, varscan2
- ADGRL4 | c.1736G>T p.C579F | Missense Mutation (SNP) | VAF 95/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100875700; called by muse, mutect2, varscan2
- AFF2 | c.1311G>T p.E437D | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV53995580; called by muse, mutect2, varscan2
- AKAP12 | c.3317T>G p.F1106C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.339); catalogued as COSV99482726; called by muse, mutect2, varscan2
- AMER2 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs866223733, COSV100766165; called by muse, mutect2
- APC2 | c.5687C>A p.A1896D | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.123); catalogued as rs768481261, COSV52019844; called by muse, mutect2, varscan2
- ARSL | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 13/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101140432; called by muse, mutect2
- ASB9 | c.629C>G p.A210G | Missense Mutation (SNP) | VAF 175/360 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100995407; called by muse, varscan2
- ASZ1 | c.122T>C p.L41S | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.104); catalogued as COSV99497829; called by muse, mutect2, varscan2
- ATF5 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100351847; called by muse, mutect2, varscan2
- ATG2B | c.2219G>T p.R740L | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as COSV100737787; called by muse, mutect2, varscan2
- ATP1A2 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs145701604; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AURKC | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as rs182340558, COSV100248783; called by muse, mutect2, varscan2
- BMP10 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 77/114 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145545108; called by muse, mutect2, varscan2
- BRCA2 | c.8525G>A p.R2842H | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80359105, COSV101204006; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- BTN3A3 | c.1078A>G p.R360G | Missense Mutation (SNP) | VAF 100/167 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs149504053; called by muse, mutect2, varscan2
- CACNA1B | c.4243A>G p.I1415V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99495782; called by muse, mutect2, varscan2
- CACNA1B | c.5330G>A p.R1777H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as rs866214887, COSV53122014; called by muse, mutect2, varscan2
- CAPZA2 | c.53C>A p.A18E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100753856; called by muse, mutect2, varscan2
- CCDC110 | c.1980A>C p.R660S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100293739; called by muse, mutect2, varscan2
- CDH3 | c.2444G>A p.R815H | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs557740168, COSV50582187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR1 | c.1703G>T p.S568I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV99417236; called by muse, mutect2, varscan2
- CLCN2 | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99658316; called by muse, mutect2, varscan2
- CLDN18 | c.137A>T p.Y46F | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100648225; called by muse, mutect2
- CLEC18B | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV100375783, COSV60576367; called by muse, mutect2, varscan2
- CLEC4A | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.61); catalogued as COSV99983546; called by muse, mutect2, varscan2
- CNTNAP2 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs1436303522, COSV100663876; called by muse, mutect2, varscan2
- COL4A5 | c.2260G>C p.A754P | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV100086891; called by muse, mutect2, varscan2
- COPS3 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1420028668, COSV99253522; called by muse, mutect2, varscan2
- CORO7 | c.234C>A p.D78E | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV99226977, COSV99227324; called by muse, mutect2, varscan2
- CRYZ | c.764A>G p.N255S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV61718065; called by muse, mutect2, varscan2
- CSMD1 | c.3505C>T p.R1169C (on ENST00000520002; = p.R1168C on NM_033225.6) | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs562188878, COSV59390336; called by muse, mutect2, varscan2
- CSMD1 | c.3292C>A p.L1098M (on ENST00000520002; = p.L1097M on NM_033225.6) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100145088; called by muse, mutect2, varscan2
- CTPS2 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 61/717 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV100826725; called by muse, mutect2
- CUL4A | c.1675C>G p.L559V (on ENST00000375440 / NM_001008895.4; = p.L459V on NM_003589.3) | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV100417096; called by muse, mutect2
- DIP2B | c.1720-1G>T p.X574_splice | Splice Site (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99998095; called by muse, mutect2, varscan2
- DOCK9 | c.813G>A p.W271* (on ENST00000376460 / NM_001366676.2; = p.W272* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100238299; called by muse, mutect2, varscan2
- EIF4B | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as rs758683560, COSV50404217; called by muse, mutect2, varscan2
- EPG5 | c.5471A>T p.Y1824F | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV99956716; called by muse, mutect2, varscan2
- EPHA5 | c.580A>G p.K194E | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99897073; called by muse, mutect2, varscan2
- ERAP2 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101163540; called by muse, mutect2, varscan2
- FAM155A | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV65569724; called by muse, mutect2, varscan2
- FAM160B2 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as rs200188247, COSV99248792; called by muse, mutect2, varscan2
- FAM47B | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV61452974; called by muse, mutect2, varscan2
- FAM9A | c.289A>G p.T97A | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV101121313; called by muse, mutect2
- FCN1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs767342630, COSV100878837; called by muse, mutect2, varscan2
- FCRL1 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV100839739; called by muse, mutect2, varscan2
- FCRL5 | c.1863C>A p.N621K | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.814); catalogued as COSV100708639; called by muse, mutect2, varscan2
- FGD1 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 226/800 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs371740120, COSV100910883; called by muse, mutect2, varscan2
- FGF3 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs782226740, COSV61925288; called by muse, mutect2, varscan2
- FOXS1 | c.950C>A p.T317N | Missense Mutation (SNP) | VAF 55/343 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs769718614, COSV99639534, COSV99639661; called by muse, mutect2, varscan2
- FRG2C | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as rs75138472; called by muse, mutect2, varscan2
- GABPA | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV61396783; called by muse, mutect2, varscan2
- GABRG1 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54951544, COSV54954244; called by muse, mutect2, varscan2
- GBF1 | c.1864G>A p.E622K (on ENST00000369983 / NM_001377137.1; = p.E621K on NM_004193.3) | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.078); catalogued as COSV100890365; called by muse, mutect2, varscan2
- GK2 | c.156G>A p.W52* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV100725872; called by muse, mutect2, varscan2
- H2BC12 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV100804592; called by muse, mutect2, varscan2
- HDAC4 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs771862462, COSV100612875; called by muse, mutect2, varscan2
- HDGFL1 | c.158C>G p.P53R | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100014521; called by muse, mutect2, varscan2
- HOXA3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57825391; called by muse, mutect2, varscan2
- IGBP1P2 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs745843784; called by muse, mutect2, varscan2
- IL18R1 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV52125850, COSV99294921; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1544A>C p.K515T | Missense Mutation (SNP) | VAF 40/358 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.192); catalogued as COSV100780860; called by muse, mutect2, varscan2
- INTS1 | c.1962G>A p.M654I | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV101247571; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.428G>A p.S143N (on ENST00000485419 / NM_001197113.1; = p.S67N on NM_014575.3) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as COSV61849110; called by muse, mutect2
- ISL1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV100045161; called by muse, mutect2, varscan2
- JHY | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs1028349128, COSV99912864; called by muse, mutect2, varscan2
- JPH2 | c.1370C>G p.A457G | Missense Mutation (SNP) | VAF 95/813 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV65904321; called by muse, mutect2, varscan2
- KCNA4 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100068665; called by muse, mutect2, varscan2
- KCNMA1 | c.2041C>A p.H681N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV54260381; called by muse, mutect2, varscan2
- KIAA1549 | c.3070C>G p.R1024G | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54322989, COSV99650071; called by muse, mutect2
- KIDINS220 | c.4568A>C p.E1523A | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.665); catalogued as COSV99875210; called by muse, mutect2
- KIF1B | c.5038C>T p.R1680* (on ENST00000377086 / NM_001365952.1; = p.R1634* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 44/137 reads (32%) | catalogued as rs907179445, COSV99822740; called by muse, mutect2, varscan2
- KIR3DL3 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV99399780; called by muse, mutect2, varscan2
- KRTAP5-8 | c.70T>A p.C24S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV101273118; called by muse, mutect2, varscan2
- LRP1B | c.2663A>T p.D888V | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100796616, COSV63341931; called by muse, mutect2, varscan2
- MAGEC1 | c.1617G>C p.W539C | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.166); catalogued as COSV99595104; called by muse, mutect2, varscan2
- MAGED1 | c.483C>G p.Y161* | Nonsense Mutation (SNP) | VAF 74/277 reads (27%) | catalogued as COSV100431431; called by muse, mutect2, varscan2
- MAST4 | c.6503G>C p.S2168T (on ENST00000403625 / NM_001164664.2; = p.S1979T on NM_015183.3) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as COSV99843274; called by muse, mutect2, varscan2
- MCOLN1 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as rs1023817233, COSV99900457; called by muse, mutect2, varscan2
- MDH1B | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100982150; called by muse, mutect2, varscan2
- MEGF6 | c.4198G>A p.D1400N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs750161200, COSV53891816; called by muse, mutect2
- MEN1 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs794728620, CD1111847, COSV53643933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MICAL2 | c.4087G>T p.D1363Y | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.632); catalogued as COSV56286511, COSV99811516; called by muse, mutect2
- MICU2 | c.169A>C p.S57R | Missense Mutation (SNP) | VAF 20/325 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101212416; called by muse, mutect2
- MKRN3 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV100090885; called by muse, mutect2, varscan2
- MST1R | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.149); catalogued as COSV99618053; called by muse, mutect2
- MTMR4 | c.1132T>C p.W378R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050848; called by muse, mutect2, varscan2
- MUC16 | c.16570A>G p.I5524V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as COSV101198713; called by muse, mutect2
- MUC5B | c.15400C>T p.R5134C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1452783636, COSV101500641, COSV71590062, COSV71592697; called by muse, mutect2, varscan2
- MYOD1 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.324); catalogued as rs1375320913, COSV100000179; called by muse, mutect2, varscan2
- MYPN | c.3767C>T p.S1256L | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542627169, COSV100589365, COSV100590591; ClinVar: uncertain significance; called by muse, mutect2
- NAB2 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1158764389, COSV100272591; called by muse, mutect2, varscan2
- NANOS3 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV100188459; called by muse, mutect2, varscan2
- NEU4 | c.1156C>T p.R386C (on ENST00000391969 / NM_001167602.3; = p.R398C on NM_080741.4) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs537701318, COSV57991377; called by muse, mutect2, varscan2
- NLRC5 | c.5415G>T p.K1805N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV52651717; called by muse, mutect2, varscan2
- NLRP10 | c.1052G>T p.C351F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100149530; called by muse, mutect2, varscan2
- OR10J5 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58386662; called by muse, mutect2
- OR4A15 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.521); catalogued as rs753902951, COSV100123895, COSV100124432; called by mutect2, varscan2
- OR4N2 | c.224T>A p.F75Y | Missense Mutation (SNP) | VAF 48/265 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs1199991690, COSV60052604; called by muse, mutect2
- OR8J3 | c.775T>C p.Y259H | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100040630; called by muse, mutect2, varscan2
- OTOGL | c.4860G>T p.K1620N (on ENST00000547103; = p.K1611N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV54019014; called by muse, mutect2, varscan2
- OTOP2 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.15); catalogued as COSV100140360; called by muse, mutect2, varscan2
- PCDHB1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.59); catalogued as COSV100128060, COSV60633461; called by muse, mutect2, varscan2
- PCDHGB1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781547082, COSV53976716; called by muse, mutect2, varscan2
- PDLIM1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1222089796, COSV100267682; called by muse, mutect2, varscan2
- PFKFB2 | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 30/160 reads (19%) | PolyPhen benign (0.022); catalogued as COSV100891901; called by muse, mutect2, varscan2
- PLXNA2 | c.2594C>T p.T865M | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs926061835, COSV65445797; called by muse, mutect2
- POLR2H | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV55602276; called by muse, mutect2, varscan2
- POM121 | c.3064G>C p.V1022L (on ENST00000434423; = p.V757L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as rs782130789, COSV99987787; called by muse, mutect2
- PRKCB | c.1703C>A p.A568D | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100332745; called by muse, mutect2, varscan2
- PRKD1 | c.1778A>T p.Q593L | Missense Mutation (SNP) | VAF 91/380 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100119502, COSV59565840; called by muse, mutect2, varscan2
- PXDNL | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1394729926, COSV62491596; called by muse, mutect2, varscan2
- RBM28 | c.1615T>A p.S539T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs543277007, COSV99775538; called by muse, mutect2, varscan2
- RETN | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV99679363; called by muse, mutect2, varscan2
- RFX4 | c.1510G>A p.A504T (on ENST00000392842 / NM_213594.3; = p.A410T on NM_032491.6) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs145361726; called by muse, mutect2, varscan2
- RGS22 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62661124; called by muse, mutect2, varscan2
- RGS8 | c.448G>A p.V150I (on ENST00000367556 / NM_001369564.2; = p.V168I on NM_033345.3) | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51117547; called by muse, mutect2, varscan2
- RTL4 | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100465778, COSV61207322; called by muse, mutect2
- RTN3 | c.451G>A p.V151I (on ENST00000377819 / NM_001265589.2; = p.V132I on NM_201428.3) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs1157477069, COSV100127390; called by muse, mutect2
- S100G | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 27/448 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs781223162, COSV100826723; called by muse, mutect2
- SACS | c.4723C>T p.R1575W | Missense Mutation (SNP) | VAF 168/241 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1426756976, COSV101207158; called by muse, varscan2
- SALL1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs763206883, COSV51754165; called by muse, mutect2, varscan2
- SC5D | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as rs142025005; called by muse, mutect2, varscan2
- SCD | c.954C>G p.N318K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100948857; called by muse, mutect2, varscan2
- SCN9A | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 65/276 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100311848; called by muse, mutect2, varscan2
- SDHAF1 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 56/734 reads (8%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV101127152; called by muse, mutect2
- SDR42E1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1045212542, COSV100200670; called by muse, mutect2, varscan2
- SERGEF | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs774761000, COSV99787003; called by muse, mutect2, varscan2
- SHANK1 | c.5207C>T p.A1736V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99520517; called by muse, mutect2, varscan2
- SLC17A7 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 81/227 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs1157506637, COSV99676733; called by muse, mutect2, varscan2
- SLC25A25 | c.15C>A p.C5* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV66086475; called by muse, mutect2, varscan2
- SLC9A3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99375756; called by muse, mutect2, varscan2
- SMG1 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV101245406; called by muse, mutect2, varscan2
- SNX15 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100100874, COSV57246970; called by muse, mutect2, varscan2
- SOD2 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496577; called by muse, mutect2, varscan2
- SOX10 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753998628, COSV100704086; called by muse, mutect2, varscan2
- SPATA31D1 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 15/274 reads (5%) | catalogued as COSV100782947, COSV61197807; called by muse, mutect2
- SPZ1 | c.1157C>T p.T386I | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV99698098; called by muse, mutect2, varscan2
- SRRM4 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV57419797; called by muse, mutect2, varscan2
- SYNE1 | c.4823C>T p.A1608V (on ENST00000367255 / NM_182961.4; = p.A1615V on NM_033071.3) | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1388098323, COSV54958316; called by muse, mutect2, varscan2
- SYNE3 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs750249553, COSV100515733; called by muse, mutect2, varscan2
- TBX3 | c.860A>G p.D287G (on ENST00000257566 / NM_016569.4; = p.D267G on NM_005996.4) | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99050530; called by muse, mutect2, varscan2
- TDRD3 | c.598A>G p.K200E | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99539900; called by muse, mutect2, varscan2
- TEX47 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs774856236, COSV51879143, COSV99787186; called by muse, mutect2, varscan2
- TLR10 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs375480992; called by muse, mutect2
- TMEM132D | c.2789C>T p.A930V | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67162726; called by muse, mutect2, varscan2
- TNFRSF14 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100859097; called by muse, mutect2, varscan2
- TOX4 | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV99398067; called by muse, mutect2, varscan2
- TSC1 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751126355, COSV100051359; ClinVar: uncertain significance / benign; called by muse, mutect2
- TSPAN13 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1013420227, COSV50439656; called by muse, mutect2, varscan2
- TTN | c.93883C>T p.R31295C (on ENST00000591111; = p.R23871C on NM_003319.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs764276622, COSV100599791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.62209C>A p.P20737T (on ENST00000591111; = p.P13313T on NM_003319.4) | Missense Mutation (SNP) | VAF 74/107 reads (69%) | PolyPhen probably damaging (0.999); catalogued as COSV100599793, COSV100622134; called by muse, mutect2, varscan2
- USH2A | c.4037G>C p.G1346A | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100230944; called by muse, mutect2, varscan2
- USP51 | c.134C>G p.T45R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs750670353, COSV101540649; called by muse, mutect2, varscan2
- VAV1 | c.558G>A p.P186= | Splice Region (SNP) | VAF 32/91 reads (35%) | catalogued as rs1434383608, COSV100408725; called by muse, mutect2, varscan2
- VLDLR | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1281202064, COSV66073301; called by muse, mutect2, varscan2
- VPS50 | c.2026C>G p.L676V | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as COSV100004588; called by muse, mutect2, varscan2
- WDR11 | c.3365A>C p.N1122T | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99676343; called by muse, mutect2, varscan2
- WDR53 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.232); catalogued as COSV100218031; called by muse, mutect2, varscan2
- WNT9A | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55297670; called by muse, mutect2
- XIRP2 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as rs370739648; called by muse, mutect2, varscan2
- ZAN | c.6412C>T p.R2138W | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs777285944, COSV61809889; called by muse, mutect2, varscan2
- ZBTB33 | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1279700834, COSV100434088; called by muse, mutect2, varscan2
- ZBTB33 | c.1373G>T p.R458I | Missense Mutation (SNP) | VAF 55/367 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100434089; called by muse, mutect2, varscan2
- ZEB1 | c.2134T>A p.S712T | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.501); catalogued as COSV100313846; called by muse, mutect2, varscan2
- ZFP42 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100478698; called by muse, mutect2, varscan2
- ZNF25 | c.378C>G p.F126L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100224532; called by muse, mutect2
- ZNF33A | c.304T>G p.L102V (on ENST00000458705 / NM_006974.3; = p.L103V on NM_006954.2) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100275596; called by muse, mutect2, varscan2
- APC | c.2328_2335del p.D777Kfs*8 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- APC | c.4240del p.V1414* | Frame Shift Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- BRWD1 | c.626del p.L209Wfs*2 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | called by mutect2, varscan2
- FCSK | c.2232_2269del p.R745Afs*2 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel
- HEXB | c.1564_1565insAA p.M522Kfs*9 | Frame Shift Ins (INS) | VAF 14/112 reads (13%) | called by mutect2, pindel, varscan2
- KRT6B | c.193_218del p.G65Rfs*80 | Frame Shift Del (DEL) | VAF 26/363 reads (7%) | called by mutect2, pindel
- MAT1A | c.1170del p.R391Gfs*50 | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | called by mutect2, pindel, varscan2
- NDST4 | c.1375del p.Y459Tfs*52 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel*, varscan2
- POTEM | c.288C>A p.S96R | Missense Mutation (SNP) | VAF 28/301 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); called by muse, varscan2
- PRAMEF10 | c.903T>A p.S301R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- PRAMEF10 | c.902G>C p.S301T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PSD2 | c.772del p.D258Mfs*13 | Frame Shift Del (DEL) | VAF 37/80 reads (46%) | called by mutect2, varscan2
- TAF9 | c.82del p.I28Lfs*9 | Frame Shift Del (DEL) | VAF 66/154 reads (43%) | called by mutect2, varscan2
- THAP8 | c.34_46del p.N12Afs*9 | Frame Shift Del (DEL) | VAF 16/131 reads (12%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1263T>A p.F421L | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- ACTN2 | c.726A>G p.E242= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV100856603; called by muse, mutect2
- ADAMTS20 | c.2301C>T p.D767= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs550143996, COSV67137561; called by muse, mutect2, varscan2
- ARHGAP6 | c.1197G>A p.K399= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV100272509; called by muse, mutect2, varscan2
- BICRA | c.1449G>A p.P483= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs1292093326, COSV101194243; called by muse, mutect2, varscan2
- BRD2 | c.123G>A p.E41= | Silent (SNP) | VAF 90/152 reads (59%) | catalogued as COSV100875588; called by muse, mutect2, varscan2
- C1orf115 | c.225C>A p.P75= | Silent (SNP) | VAF 64/189 reads (34%) | catalogued as COSV54274021; called by muse, mutect2, varscan2
- CAPRIN2 | c.1215T>C p.D405= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV51832393; called by muse, mutect2, varscan2
- CDHR3 | c.762C>T p.I254= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as rs777325254, COSV58416905; called by muse, mutect2, varscan2
- CELF5 | c.807C>G p.G269= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99485760; called by muse, mutect2, varscan2
- COL18A1 | c.2733C>T p.P911= (on ENST00000359759 / NM_130444.3; = p.P676= on NM_030582.4) | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs1306196387, COSV100700530; called by muse, mutect2, varscan2
- DGKB | c.1788A>T p.A596= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV51770284; called by muse, mutect2, varscan2
- DNAH3 | c.1020C>T p.N340= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs201753088; called by muse, mutect2
- DNAJC6 | c.2529A>G p.V843= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs1459630301, COSV54777376; called by muse, mutect2, varscan2
- DYRK2 | c.1497G>A p.A499= (on ENST00000344096 / NM_006482.3; = p.A426= on NM_003583.4) | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as COSV59846575; called by muse, mutect2, varscan2
- EVPL | c.3852C>T p.H1284= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs567587180, COSV56907566; called by muse, mutect2, varscan2
- FAM24B | c.87G>T p.A29= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as rs777497894, COSV100158643, COSV59028260; called by muse, mutect2, varscan2
- FANCL | c.129T>G p.P43= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs746046267, COSV99287336; called by muse, mutect2, varscan2
- FBXL7 | c.390C>G p.P130= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100309308; called by muse, mutect2, varscan2
- FKBP10 | c.744A>G p.P248= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as COSV100387761; called by muse, mutect2, varscan2
- FLG | c.1251T>C p.S417= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV100911000; called by muse, mutect2
- GULP1 | c.492A>G p.K164= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV100770312; called by muse, mutect2, varscan2
- HTT | c.6675G>A p.L2225= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as rs1323253450, COSV100750544; called by muse, mutect2, varscan2
- IPO11 | c.2736C>T p.P912= | Silent (SNP) | VAF 124/642 reads (19%) | catalogued as COSV100320360, COSV57576900; called by muse, mutect2, varscan2
- KCNC2 | c.531C>T p.G177= | Silent (SNP) | VAF 63/374 reads (17%) | catalogued as COSV54364138; called by muse, mutect2, varscan2
- KLC1 | c.1149G>A p.T383= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as rs142008310; called by muse, mutect2, varscan2
- LMX1B | c.933G>A p.P311= | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as rs145052881, COSV100826950; called by muse, mutect2, varscan2
- LRRIQ3 | c.658T>C p.L220= | Silent (SNP) | VAF 49/403 reads (12%) | catalogued as rs374358600; called by muse, mutect2, varscan2
- MMP3 | c.852T>A p.P284= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV55406798; called by muse, mutect2
- MPHOSPH8 | c.282T>A p.I94= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV64056191; called by muse, mutect2, varscan2
- NKG7 | c.162C>T p.Y54= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as rs1324622777, COSV52467716; called by muse, mutect2, varscan2
- OR5R1 | c.297C>T p.T99= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100393308; called by muse, mutect2, varscan2
- PCDHA3 | c.969G>A p.T323= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as COSV100793231; called by muse, mutect2
- PCDHA6 | c.1614C>T p.R538= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as COSV100971279; called by muse, mutect2, varscan2
- PCDHB12 | c.2055G>T p.S685= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs543195348, COSV53393662, COSV53399217; called by muse, mutect2, varscan2
- PFKP | c.1503C>T p.N501= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as rs370592480; called by muse, mutect2, varscan2
- PGGHG | c.1782G>A p.A594= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs745854083, COSV66888540; called by muse, mutect2, varscan2
- PLXNA3 | c.3675G>A p.A1225= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs782275281, COSV100859841; called by muse, mutect2, varscan2
- RIPOR3 | c.459C>T p.R153= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs374374141; called by muse, mutect2, varscan2
- SART1 | c.1164C>T p.S388= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs139408234, COSV56712462; called by muse, mutect2, varscan2
- SEL1L | c.990G>A p.S330= | Silent (SNP) | VAF 52/85 reads (61%) | catalogued as rs754518891, COSV60921349; called by muse, mutect2, varscan2
- SNX19 | c.2355A>G p.K785= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99772910; called by muse, mutect2
- SNX20 | c.852C>T p.F284= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV56056757; called by muse, mutect2, varscan2
- SPART | c.441T>G p.T147= | Silent (SNP) | VAF 12/139 reads (9%) | catalogued as COSV100768605; called by muse, mutect2
- STAB2 | c.2586A>G p.G862= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV101185719; called by muse, mutect2, varscan2
- TET3 | c.3300C>T p.C1100= | Silent (SNP) | VAF 57/96 reads (59%) | catalogued as rs779499652, COSV101327678; called by muse, mutect2, varscan2
- TMEM132D | c.621G>A p.T207= | Silent (SNP) | VAF 54/93 reads (58%) | catalogued as rs768123163, COSV101396847, COSV101398768; called by muse, mutect2, varscan2
- TRAPPC10 | c.2562C>G p.L854= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV99378311; called by muse, mutect2, varscan2
- TTN | c.51333G>A p.P17111= (on ENST00000591111; = p.P9687= on NM_003319.4) | Silent (SNP) | VAF 69/92 reads (75%) | catalogued as rs111262307, COSV59904077; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TULP1 | c.249G>A p.A83= | Silent (SNP) | VAF 19/182 reads (10%) | catalogued as rs377105125; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- MIR363 | n.5G>T | RNA (SNP) | VAF 63/445 reads (14%) | called by muse, mutect2, varscan2
- MIR99AHG | n.700G>T | RNA (SNP) | VAF 73/381 reads (19%) | called by muse, mutect2, varscan2
- MYL1 | c.133-260G>A | Intron (SNP) | VAF 48/411 reads (12%) | catalogued as COSV100498659; called by muse, mutect2, varscan2
- NRG1 | c.700+610G>A | Intron (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99827952; called by muse, mutect2
- VKORC1 | chr16:31095465 G>T | 5'Flank (SNP) | VAF 82/187 reads (44%) | catalogued as COSV100161665; called by muse, mutect2, varscan2
- XIRP2 | c.*801C>A | 3'UTR (SNP) | VAF 160/353 reads (45%) | catalogued as COSV99739819; called by muse, mutect2, varscan2
